Somatic mutation profile of tumor specimen TCGA-FZ-5923-01A (aliquot TCGA-FZ-5923-01A-12D-1609-08) from TCGA case TCGA-FZ-5923, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IV; Tumor grade: G1; Age at diagnosis: 71.8 years (26,216 days).
Specimen TCGA-FZ-5923-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 948f2748-45c0-40b9-b799-adc33a4b8033.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FZ-5923-11A (Solid Tissue Normal), aliquot TCGA-FZ-5923-11A-01D-1609-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6ef2c30-172f-48b5-b530-6e31f392c053

The open-access MAF lists 65 somatic variants for this specimen: 51 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 47, Silent 14, Nonsense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FANK1 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | hotspot (GDC flag); catalogued as rs202109621, COSV64160606; called by muse, mutect2
- FBN1 | c.3217G>A p.E1073K | Missense Mutation (SNP) | VAF 32/337 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs137854478, CM950442, COSV100356648; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 12/142 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCG5 | c.916T>C p.S306P | Missense Mutation (SNP) | VAF 70/897 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99575723; called by muse, mutect2
- ACSS1 | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 25/755 reads (3%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs1212329188, COSV60217871; called by muse, mutect2
- ADAM23 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 48/413 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as rs376901578, COSV100009148; called by muse, mutect2, varscan2
- ADAMTS5 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as rs1452439093, COSV99538524; called by muse, mutect2, varscan2
- ADGRE2 | c.1895C>T p.T632M | Missense Mutation (SNP) | VAF 48/401 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.098); catalogued as rs45563436, COSV100216610; called by muse, mutect2, varscan2
- ADRA1A | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 44/712 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as rs367786537, COSV99369834; called by muse, mutect2
- AGBL5 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 44/460 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747996062, COSV59938069; called by muse, mutect2
- C5orf49 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 94/738 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758441281, COSV101296921; called by muse, mutect2, varscan2
- CAVIN2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 65/853 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as rs1249829378, COSV100414407; called by muse, mutect2
- CCDC170 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 37/541 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV53340091; called by muse, mutect2
- CHRNA1 | c.529G>A p.V177I (on ENST00000261007 / NM_001039523.3; = p.V152I on NM_000079.4) | Missense Mutation (SNP) | VAF 24/433 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs137852807, CM030009, COSV53684144; called by muse, mutect2
- CHST6 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.251); catalogued as CM104646, COSV100178680; called by muse, mutect2, varscan2
- DLGAP4 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 54/416 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs762577016, COSV59422245; called by muse, mutect2, varscan2
- EP400 | c.1649T>C p.L550S | Missense Mutation (SNP) | VAF 50/723 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100202566; called by muse, mutect2
- ETNPPL | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 24/345 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV99625179; called by muse, mutect2
- FLT1 | c.2557C>A p.P853T | Missense Mutation (SNP) | VAF 101/864 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.304); catalogued as COSV99169901; called by muse, mutect2, varscan2
- FMO2 | c.1151T>A p.L384H | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99269392; called by muse, mutect2
- JAKMIP3 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373222736; called by muse, mutect2
- LINGO2 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 144/970 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs781520934, COSV58057149; called by muse, mutect2, varscan2
- LRCH3 | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 38/353 reads (11%) | catalogued as COSV100605313; called by muse, mutect2, varscan2
- NEFL | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1246614827, COSV55338619; called by muse, mutect2
- NRBP1 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1379513593, COSV51996254; called by muse, mutect2, varscan2
- NUP54 | c.194C>G p.T65S | Missense Mutation (SNP) | VAF 236/1869 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV53576780, COSV99345532; called by muse, mutect2, varscan2
- OBSCN | c.7666C>T p.R2556W | Missense Mutation (SNP) | VAF 33/416 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs566340039, COSV52738921; called by muse, mutect2
- OR8B12 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 49/426 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs761900183, COSV60911045; called by muse, mutect2, varscan2
- OSBPL10 | c.1534C>T p.H512Y | Missense Mutation (SNP) | VAF 52/620 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV101160020; called by muse, mutect2
- PCDHB2 | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 56/1238 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV99167021; called by muse, mutect2
- PEX5L | c.1693T>G p.F565V | Missense Mutation (SNP) | VAF 93/644 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99830273; called by muse, mutect2, varscan2
- PRICKLE2 | c.1873C>T p.R625* (on ENST00000295902; = p.R569* on NM_198859.4) | Nonsense Mutation (SNP) | VAF 80/902 reads (9%) | catalogued as COSV55765923, COSV55772339, COSV99898213; called by muse, mutect2
- RBMXL2 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV100182614; called by muse, mutect2, varscan2
- RSBN1L | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 80/719 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as rs769360757, COSV100616280; called by muse, mutect2, varscan2
- SARDH | c.2680G>C p.G894R | Missense Mutation (SNP) | VAF 19/449 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); catalogued as COSV100898506; called by muse, mutect2
- SDK2 | c.5488G>A p.V1830M | Missense Mutation (SNP) | VAF 86/942 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.264); catalogued as rs146597384; called by muse, mutect2
- SETD2 | c.5636G>A p.R1879H | Missense Mutation (SNP) | VAF 38/994 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1357325164, COSV100340114; called by muse, mutect2
- SHKBP1 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 60/766 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1450366188, COSV52539312; called by muse, mutect2
- SLC45A4 | c.596A>G p.H199R (on ENST00000517878 / NM_001286646.2; = p.H148R on NM_001080431.2) | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99201124; called by muse, mutect2, varscan2
- SLIT3 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as rs772201491, COSV100270781; called by muse, mutect2
- SOX8 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs559279447, COSV99559415; called by muse, mutect2, varscan2
- SPZ1 | c.1171G>T p.D391Y | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV99698305; called by muse, mutect2
- SRP72 | c.38C>G p.A13G | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.137); catalogued as COSV100714403; called by muse, mutect2, varscan2
- THAP2 | c.431A>T p.E144V | Missense Mutation (SNP) | VAF 34/295 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100350629; called by muse, mutect2, varscan2
- TTN | c.28813G>A p.D9605N (on ENST00000591111; = p.D8678N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/150 reads (9%) | PolyPhen benign (0.157); catalogued as COSV100635429; called by muse, mutect2
- TTN | c.12094G>A p.V4032M (on ENST00000591111; = p.V3986M on NM_003319.4) | Missense Mutation (SNP) | VAF 76/543 reads (14%) | catalogued as rs140847585, COSV100635432; called by muse, mutect2, varscan2
- XXYLT1 | c.814A>G p.N272D | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV100118854; called by muse, mutect2
- ZFHX3 | c.6121C>A p.P2041T | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1274205202, COSV99215315; called by muse, mutect2
- ATM | c.2839-3_2843del p.X947_splice | Splice Site (DEL) | VAF 28/224 reads (13%) | called by mutect2, pindel
- NACC2 | c.65A>G p.E22G | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RBBP8 | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 118/906 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ADCYAP1 | c.468C>T p.A156= | Silent (SNP) | VAF 57/960 reads (6%) | catalogued as rs1249976616, COSV52487177; called by muse, mutect2
- BEND2 | c.2055C>T p.C685= | Silent (SNP) | VAF 34/344 reads (10%) | catalogued as rs745334763, COSV66214935; called by muse, mutect2, varscan2
- FMN2 | c.4050G>A p.K1350= | Silent (SNP) | VAF 19/630 reads (3%) | catalogued as COSV100147813; called by muse, mutect2
- FOXI2 | c.651G>A p.A217= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100511127; called by muse, mutect2, varscan2
- HECTD4 | c.10623C>T p.T3541= | Silent (SNP) | VAF 16/273 reads (6%) | catalogued as rs1360333455, COSV101108436; called by muse, mutect2
- LAS1L | c.1557C>T p.G519= | Silent (SNP) | VAF 22/322 reads (7%) | catalogued as COSV100408732; called by muse, mutect2
- LRTM2 | c.765C>T p.D255= | Silent (SNP) | VAF 24/270 reads (9%) | catalogued as rs749108772, COSV54564332, COSV99766791; called by muse, mutect2
- NSD3 | c.3954G>A p.Q1318= | Silent (SNP) | VAF 22/264 reads (8%) | catalogued as COSV100395897; called by muse, mutect2
- PCSK4 | c.861C>T p.R287= | Silent (SNP) | VAF 23/274 reads (8%) | catalogued as rs767601485, COSV99278920; called by muse, mutect2
- PDE1C | c.819C>T p.T273= | Silent (SNP) | VAF 66/644 reads (10%) | catalogued as rs758775742, COSV58512212; called by muse, mutect2, varscan2
- RAP1GDS1 | c.663T>C p.S221= (on ENST00000408927 / NM_001100427.2; = p.S222= on NM_021159.5) | Silent (SNP) | VAF 31/304 reads (10%) | catalogued as COSV99217525; called by muse, mutect2, varscan2
- RNF144A | c.861C>T p.D287= | Silent (SNP) | VAF 20/346 reads (6%) | catalogued as rs753914440; called by muse, mutect2
- SENP7 | c.216C>T p.I72= | Silent (SNP) | VAF 28/930 reads (3%) | catalogued as COSV100054030; called by muse, mutect2
- TMEM214 | c.813C>T p.T271= | Silent (SNP) | VAF 67/780 reads (9%) | catalogued as rs532355662, COSV53192803; called by muse, mutect2
